Surgical pathology report (de-identified scan), TCGA case TCGA-EV-5903, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-EV-5903-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

SPECIMEN

- A. KIDNEY - 1. Base of left renal mass
B. KIDNEY - 2. Left renal mass.

CLINICAL INFORMATION

Left renal mass. History: Liver transplant

GROSS DESCRIPTION

The specimen is received in two parts, both labeled with the patient's name

Part A is received fresh for frozen section diagnosis additionally labeled "base of left renal mass" and consists of a 0.4 x 0.2 x 0.1 cm pink-tan tissue fragment, which is submitted entirely. The remainder of the tissue is submitted in cassette (A1).

Frozen section diagnosis:

FSA1 – Base of renal mass – "Renal tubules with fibrosis. No evidence of carcinoma."

Part B is also received fresh additionally labeled "renal mass (left)" and consists of a 39 gm, 7 x 4.5 x 3.5 cm portion of kidney with a 4.5 x 3.2 cm oval resection plane. Within the tissue a well-demarcated tan pale 3.5 x 3 x 2 cm mass is seen. A thin layer of fat covers most of the specimen, except for a 1.5 cm area. The renal resection margin is inked red. The remainder of the surface including the fat is inked in black. The cut surface of the tumor is uniformly tan-white and friable. It is well-demarcated from the red-tan renal parenchyma. The tumor comes to within 0.5 cm of the resection plane. Representative sections are submitted in cassettes (B1)-(B5). Gross photos obtained.

SLIDE KEY

B1 – tumor nearest to resection margin

B2-B5 – additional representative sections, perpendicular to resection plane.

Approximately 50% of tumor is submitted.

MICROSCOPIC DESCRIPTION

[page 2 of 2]
Multiple H&E-stained slides are examined. Sections show a well-circumscribed papillary renal cell carcinoma with prominent aggregates of foamy histiocytes and cholesterol clefting. The individual cells have well-defined cell borders with pale to eosinophilic cytoplasm and somewhat enlarged nuclei with small nucleoli. The tumor comes to within 0.4 cm of the resection margin. Fuhrman nuclear grade is 2.

Surgical Pathology Cancer Case Summary, Kidney

SPECIMEN TYPE: Left partial nephrectomy.

TUMOR SIZE: 3.5 x 3 x 2 cm.

MACROSCOPIC EXTENT OF TUMOR: Limited to kidney.

HISTOLOGIC TYPE: Papillary renal cell carcinoma.

HISTOLOGIC GRADE: G2: Nuclei slightly irregular, approximately 15 micron; small nucleoli evident.

EXTENT OF INVASION: T1a: Tumor $\leq$ 7 cm in greatest dimension, limited to the kidney.

MARGINS: Margins uninvolved by tumor.

BLOOD/LYMPHATIC VESSEL INVASION: Not seen.

ADRENAL GLAND: Not present.

REGIONAL LYMPH NODES: NX: Cannot be assessed.

DISTANT METASTASIS: MX: Cannot be assessed.

ADDITIONAL FINDINGS: Abundant cholesterol clefting, nearby renal tissue with chronic inflammation.

FINAL DIAGNOSIS

BASE OF RENAL MASS BIOPSY

- Negative for malignancy.

KIDNEY, LEFT, RENAL MASS, PARTIAL NEPHRECTOMY

- Papillary renal cell carcinoma, 3.5 cm diameter, Fuhrman grade 2.
- Tumor is 0.4 cm from the nearest resection margin.
- Lesion is excised.

CPT CODES: 88305x1, 88307x1, 88331x1

Source: NCI Genomic Data Commons file 35ea335b-a624-4ca8-bcb3-05246daf5272 (TCGA-EV-5903.C37146FA-323B-46B5-B1B4-40B09E2EFEF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).